Gene-level copy-number profile of tumor specimen TCGA-05-4250-01A from TCGA case TCGA-05-4250, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79.6 years (29,068 days).
Specimen TCGA-05-4250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.47ed8f8d-e76a-41e8-8bd7-580f3e0a589e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4250-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec68ad51-5328-4068-8c34-625ce0d72979

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 15,784; copy number 3: 25,314; copy number 4: 11,409; copy number 5: 3,740; copy number 6: 2,987; copy number 7: 241; copy number 8: 120; copy number 9: 54; copy number 10: 2; copy number 12: 3; copy number 13: 164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4250-01A-01D-1877-01): tumor purity 0.5, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 584 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,219,849–43,233,394, 4 genes, copy number 9: AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr2:43,408,307–43,408,412, 1 gene, copy number 9: RNU6-958P.
- chr12:16,188,485–28,978,685, 196 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr12:30,926,428–31,106,830, 7 genes, copy number 7 (within-gene range 2–7): TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3.
- chr12:31,280,422–32,646,050, 47 genes, copy number 8 (within-gene range 2–8): AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr12:32,985,838–32,993,754, 2 genes, copy number 10: ASS1P14, AC087311.1.
- chr12:52,164,115–53,079,404, 60 genes, copy number 8: LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3.
- chr19:43,891,804–45,873,797, 116 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:54,208,087–58,719,238, 76 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:60,755,001–62,068,437, 15 genes, copy number 7: AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2.
- chr20:63,400,208–64,313,132, 60 genes, copy number 8–9: KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
